CCDI case PBBZKC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5e779cff-78c9-4022-a567-cf8f683498c7

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.9 years (5,459 days).

Biospecimens (3 samples)
- Sample 0DLPZC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLPZF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLQ03: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
